Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A6QY, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A6QY-01A (Primary Tumor).

Patient ID:

Surgical Date:

Gross Description: There is a skin flap up to 7 x 5 cm in size, with a black spot up to 2 x 1.6 cm in its size. Tumor protrudes above the skin surface. Tumor gross thickness is up to 5 mm. Resection margins are of the normal structure.

Microscopic Description: Malignant melanoma of the skin with focal surface ulceration. Tumor Breslow thickness is 10 mm.

Diagnosis Details: Tumor Features: Ulcerated, Tumor Extent: More than 4 mm with or without ulceration, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin, shoulder

Tumor size: 1.6 x 1 x 2 cm

Tumor features: Ulcerated, Pigmented

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade: Not specified

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Tumor Breslow thickness is 10 mm.

Comments: None

ICD-O-3
Melanoma, malignant NOS
8720/3
Site C44.9 Skin NOS
C44.9
path
Skin of shoulder
C44.6
JW 7/5/13

Use of Synchronous Primary Note		✓

Source: NCI Genomic Data Commons file 9733fd83-40d8-4f46-bbec-0c4d0f7bae89 (TCGA-EB-A6QY.FD4116F2-8A21-48DF-9639-E840F7010657.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).